Somatic mutation profile of tumor specimen BA2674D (aliquot aq-BA2674D) from BEATAML1.0 case 2301, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.9 years (25,886 days).
Specimen BA2674D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 536be996-ca7d-4485-a70e-e35cedeea346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2458D (Solid Tissue Normal), aliquot aq-BA2458D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff5cadc7-2133-4051-835e-f52cbc6aae09

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KALRN | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs926123706, COSV53752228; called by muse, mutect2
- MYH13 | c.5641T>A p.S1881T | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52837022, COSV99353665; called by muse, mutect2
- TRRAP | c.11164G>T p.D3722Y (on ENST00000359863 / NM_001244580.1; = p.D3693Y on NM_003496.3) | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100705490; called by muse, mutect2
- SAMD4A | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2
- XIAP | c.*6158G>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs990299775; called by muse, mutect2, varscan2
